Gene-level copy-number profile of tumor specimen TCGA-VD-A8KI-01A from TCGA case TCGA-VD-A8KI, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.4 years (24,966 days).
Specimen TCGA-VD-A8KI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.96bb74dc-b026-4b7a-ae01-c5b7a3996d8b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-A8KI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-VD-A8KI-01A|TCGA-VD-A8KI-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06ec9ba6-cb0c-40bf-bd87-2dc40c550cd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,047; copy number 2: 46,463; copy number 3: 3,776; copy number 6: 1,534.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-A8KI-01A-11D-A39V-01): tumor purity 0.95, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,534 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
